TCGA case TCGA-CN-A6UY — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Base of tongue; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/602f2512-00b6-44b6-9ed6-f8b010224f8c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; ICD-10 code: C01; Tissue or organ of origin: Base of tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 57.4 years (20,967 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N2a; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T3; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 713 days (2.0 years).
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 2; Lymph nodes tested: 43; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 59 days; Days to treatment end: 106 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 59 days; Days to treatment end: 101 days; Treatment dose: 6,900 cGy; Treatment outcome: Complete Response; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 106 days; Treatment outcome: No Measurable Disease.

Follow-up (2 entries)
- Days to follow up: 307 days; Disease response: Tumor Free.
- Days to follow up: 713 days (2.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Positive.
- Involved Tissue, NOS human papillomavirus (ISH): Positive.

Exposures
- Exposure type: Smokeless Tobacco; Age at last exposure: 48; Age at onset: 38.
- Exposure type: Smokeless Tobacco; Age at last exposure: 48.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1973; Tobacco smoking quit year: 2003.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CN-A6UY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 170 mg.
  Slide TCGA-CN-A6UY-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CN-A6UY-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 4; Alcohol history documented: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: Yes; Definitive treatment method: Surgery; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 713 days; disease-specific survival: no event (censored), 713 days; progression-free interval: no event (censored), 713 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CN-A6UY-01A-12D-A34I-01): tumor purity 0.85, ploidy 2.02, whole-genome doublings 0.
